Somatic mutation profile of cancer-model specimen HCM-WCMC-0945-C54-85A (3D Organoid; aliquot HCM-WCMC-0945-C54-85A-01D-A937-36), derived from the primary tumor of HCMI case HCM-WCMC-0945-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 65.0 years (23,744 days).
Specimen HCM-WCMC-0945-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37a45d8c-d9ea-4bd7-a1ce-01afad96ed41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0945-C54-11A (Slides), aliquot HCM-WCMC-0945-C54-11A-15D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3001a42-a979-4b1c-bd11-4c9b99b0e888

The open-access MAF lists 453 somatic variants for this specimen: 330 protein-altering or splice-affecting, 106 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 106, Frame Shift Del 47, Nonsense Mutation 15, Frame Shift Ins 12, Intron 8, 3'UTR 5, In Frame Del 2, Splice Region 2, 5'UTR 2, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 127/325 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912679, CM080031, COSV55117476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 56/363 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 336/725 reads (46%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, varscan2
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 199/418 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 255/517 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DOK7 | c.1263dup p.S422Lfs*97 | Frame Shift Ins (INS) | VAF 288/659 reads (44%) | catalogued as rs606231129; ClinVar: pathogenic; called by mutect2, varscan2
- DYNC1H1 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 54/500 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs863223361, CM163684, COSV64138416; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2300_2308dup p.A767_V769dup | In Frame Ins (INS) | VAF 126/328 reads (38%) | hotspot (GDC flag); catalogued as rs727504263; ClinVar: drug response; called by mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 228/447 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 132/255 reads (52%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 128/279 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RBM39 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 138/314 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53614904; called by muse, mutect2, varscan2
- ADAMTSL5 | c.996del p.A333Qfs*95 | Frame Shift Del (DEL) | VAF 78/646 reads (12%) | catalogued as rs747391301; called by mutect2, varscan2
- ADGRB3 | c.2939G>T p.R980I | Missense Mutation (SNP) | VAF 182/374 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53260222; called by muse, mutect2, varscan2
- ANO8 | c.2176_2177del p.S726Afs*53 | Frame Shift Del (DEL) | VAF 210/440 reads (48%) | catalogued as rs761093570; called by mutect2, varscan2
- ANPEP | c.969del p.I324Sfs*37 | Frame Shift Del (DEL) | VAF 237/500 reads (47%) | catalogued as COSV55594433; called by mutect2, varscan2
- ARID1A | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 239/646 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1392898464; called by muse, mutect2, varscan2
- ATP2B3 | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 105/436 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54864748; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 173/322 reads (54%) | catalogued as rs771098505; called by mutect2, varscan2
- BLVRA | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 216/427 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs138692014; called by muse, mutect2, varscan2
- C3 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 205/471 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs945676974, COSV55573557; called by muse, mutect2, varscan2
- CCDC39 | c.2040_2043del p.C680Wfs*15 | Frame Shift Del (DEL) | VAF 40/381 reads (10%) | catalogued as rs1174553107; called by mutect2, varscan2
- CCDC50 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 136/275 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776014358, COSV66667353; called by muse, varscan2
- CCDC54 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 168/361 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs1327218940, COSV53758551; called by muse, mutect2, varscan2
- CDC42BPB | c.1373G>A p.S458N | Missense Mutation (SNP) | VAF 33/422 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV63474976; called by muse, mutect2
- CEACAM5 | c.2093G>T p.G698V | Missense Mutation (SNP) | VAF 222/446 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.113); catalogued as COSV55754395; called by muse, mutect2, varscan2
- CHD7 | c.2480A>G p.Y827C | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs769974585; called by muse, mutect2, varscan2
- CHRNA4 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 76/783 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV64719561; called by muse, mutect2
- CLEC1A | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 185/419 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.208); catalogued as rs147882348, COSV100191187, COSV59531017; called by muse, mutect2, varscan2
- CNGA3 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 175/374 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs77733216, COSV55625289; called by muse, mutect2, varscan2
- CPA3 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 190/404 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1480716038; called by muse, mutect2
- CUBN | c.6157C>T p.L2053F | Missense Mutation (SNP) | VAF 166/373 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs751834059, COSV100911747, COSV64726423; called by muse, mutect2, varscan2
- CYLD | c.2305A>T p.I769F | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1489875475, CD051729, COSV61093604, COSV61095598; called by muse, mutect2, varscan2
- DCAF17 | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 166/327 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs1464028164; called by muse, mutect2, varscan2
- DCAF8L2 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 233/503 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV101446081; called by muse, mutect2, varscan2
- DDX3X | c.826G>C p.E276Q (on ENST00000399959; = p.E277Q on NM_001356.5) | Missense Mutation (SNP) | VAF 153/357 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67864271; called by muse, mutect2, varscan2
- DENND11 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 329/694 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs369765513; called by muse, mutect2, varscan2
- DEPDC5 | c.2054G>A p.R685H (on ENST00000400246; = p.R754H on NM_014662.5) | Missense Mutation (SNP) | VAF 58/546 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as rs542384516; ClinVar: uncertain significance; called by muse, mutect2
- DGKD | c.2564del p.G855Vfs*48 (on ENST00000264057 / NM_152879.3; = p.G811Vfs*48 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 90/300 reads (30%) | catalogued as rs35538077; called by mutect2, varscan2
- DIDO1 | c.6101del p.P2034Rfs*240 | Frame Shift Del (DEL) | VAF 284/574 reads (49%) | catalogued as COSV56634983; called by mutect2, varscan2
- DKK2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 228/433 reads (53%) | catalogued as rs1254069801, COSV53397188, COSV53400080; called by muse, mutect2, varscan2
- DMRTA2 | c.1391G>C p.S464T | Missense Mutation (SNP) | VAF 177/677 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV68672351; called by muse, mutect2, varscan2
- DNAAF5 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs773921234; called by muse, mutect2, varscan2
- DNAH5 | c.7168G>A p.V2390I | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs751936457; called by muse, mutect2
- DNHD1 | c.10373G>A p.R3458Q | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1465065465, COSV104392333; called by muse, mutect2, varscan2
- DPYSL3 | c.1545del p.A516Qfs*15 | Frame Shift Del (DEL) | VAF 260/517 reads (50%) | catalogued as COSV58330771; called by mutect2, varscan2
- DST | c.13633C>T p.P4545S (on ENST00000361203 / NM_001374722.1; = p.P2133S on NM_015548.5) | Missense Mutation (SNP) | VAF 103/393 reads (26%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.924); catalogued as rs751065169; called by muse, mutect2, varscan2
- EML2 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 171/392 reads (44%) | catalogued as rs35928591, COSV55598462; called by muse, mutect2, varscan2
- ENOX2 | c.361C>T p.R121* (on ENST00000338144 / NM_001382520.1; = p.R92* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 194/477 reads (41%) | catalogued as rs778865428; called by muse, mutect2, varscan2
- EPHA2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 276/544 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754639981, COSV64452591; called by muse, mutect2, varscan2
- EPN1 | c.1680del p.M561* (on ENST00000270460 / NM_001321263.1; = p.M535* on NM_013333.3) | Frame Shift Del (DEL) | VAF 259/564 reads (46%) | catalogued as rs1306515040; called by mutect2, varscan2
- ERBB3 | c.1783G>C p.G595R | Missense Mutation (SNP) | VAF 193/467 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57253288; called by muse, mutect2, varscan2
- FAM160B2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 193/372 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs933078380; called by muse, mutect2, varscan2
- FBXO30 | c.1661G>T p.R554M | Missense Mutation (SNP) | VAF 191/367 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99395452; called by muse, mutect2, varscan2
- FLNC | c.7732G>A p.G2578S | Missense Mutation (SNP) | VAF 185/391 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs566747845, COSV99071403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FN1 | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 242/534 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs370103949; called by muse, mutect2, varscan2
- FOXA1 | c.713C>A p.P238Q | Missense Mutation (SNP) | VAF 198/630 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566824301; called by muse, varscan2
- FOXA1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 321/607 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs752702606; called by muse, varscan2
- FRMD5 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 112/327 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs150697882; called by muse, mutect2, varscan2
- FUT4 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 273/568 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1253711275; called by muse, mutect2, varscan2
- GNL3L | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201728319; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 242/673 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1230580971, COSV101417052, COSV71180979; called by muse, mutect2, varscan2
- HCN1 | c.1727A>G p.Y576C | Missense Mutation (SNP) | VAF 202/405 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57494297; called by muse, mutect2, varscan2
- HIVEP2 | c.4417C>T p.L1473F | Missense Mutation (SNP) | VAF 223/503 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs765987550; called by muse, mutect2, varscan2
- HOOK2 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 55/419 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.714); catalogued as rs1452421779; called by muse, mutect2, varscan2
- HS3ST2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 125/530 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV54465233; called by muse, mutect2, varscan2
- HSPA8 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 144/290 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.607); catalogued as COSV57083414; called by muse, mutect2, varscan2
- INPP1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 119/446 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as rs1400197777; called by muse, mutect2, varscan2
- INTS12 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 172/338 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.401); catalogued as rs1466709231, COSV100415763; called by muse, mutect2, varscan2
- ITIH4 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56578027; called by muse, mutect2
- ITLN2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 163/351 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs912358230, COSV63537517; called by muse, mutect2, varscan2
- JADE1 | c.2486G>A p.S829N | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1470142944; called by muse, mutect2, varscan2
- KANK2 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62007353; called by muse, mutect2
- KATNIP | c.4316C>T p.A1439V | Missense Mutation (SNP) | VAF 207/407 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs763468216; called by muse, mutect2, varscan2
- KIF26B | c.4319C>T p.P1440L | Missense Mutation (SNP) | VAF 30/859 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1272543569, COSV63649568; called by muse, mutect2
- KIF2B | c.411C>A p.S137R | Missense Mutation (SNP) | VAF 254/485 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV52127037, COSV52134855; called by muse, mutect2, varscan2
- LONP1 | c.2633C>T p.A878V | Missense Mutation (SNP) | VAF 248/542 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867925414, COSV56799253; called by muse, varscan2
- LTBP2 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 342/682 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs781644874; called by muse, mutect2, varscan2
- MACF1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 133/289 reads (46%) | catalogued as COSV57102933, COSV57103434; called by muse, mutect2, varscan2
- MACROD2 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 144/301 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV54027769; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 139/521 reads (27%) | catalogued as rs752869239; called by mutect2, varscan2
- MAPRE2 | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV55817203; called by muse, mutect2, varscan2
- MCM4 | c.1553A>G p.Q518R | Missense Mutation (SNP) | VAF 224/470 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs375382737; called by muse, mutect2, varscan2
- MED14 | c.3589G>A p.G1197S | Missense Mutation (SNP) | VAF 210/629 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as rs1007967830; called by muse, mutect2, varscan2
- MEI4 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 190/385 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as rs1424549035; called by muse, mutect2, varscan2
- MEX3A | c.200dup p.G68Rfs*89 | Frame Shift Ins (INS) | VAF 46/118 reads (39%) | catalogued as rs773021630; called by mutect2, varscan2
- MICAL2 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 234/418 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773570310; called by muse, varscan2
- MOSPD1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 132/264 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143435005; called by muse, varscan2
- MS4A2 | c.498A>T p.K166N | Missense Mutation (SNP) | VAF 180/393 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1481946030; called by muse, mutect2, varscan2
- MTERF4 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 42/451 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.049); catalogued as rs367795757; called by muse, mutect2, varscan2
- MYOF | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 161/325 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.655); catalogued as rs376117217; called by muse, mutect2, varscan2
- MYT1 | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 28/900 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as rs759011128, COSV60514422; called by muse, mutect2
- NOTCH3 | c.4534G>A p.V1512M | Missense Mutation (SNP) | VAF 80/806 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as rs375087797; called by muse, mutect2
- NTRK2 | c.1931C>A p.P644Q (on ENST00000323115 / NM_001369534.1; = p.P660Q on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 215/479 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs201105177, COSV52862623, COSV52889219; called by muse, mutect2, varscan2
- OR6S1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 255/544 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV57839130; called by muse, mutect2, varscan2
- PACS2 | c.252dup p.S85Qfs*57 | Frame Shift Ins (INS) | VAF 168/372 reads (45%) | catalogued as rs782816086; called by mutect2, varscan2
- PATL1 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 31/350 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs751352329, COSV55689148; called by muse, mutect2
- PCDH19 | c.3110G>T p.R1037M (on ENST00000373034 / NM_001184880.2; = p.R989M on NM_020766.3) | Missense Mutation (SNP) | VAF 372/764 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55270202; called by muse, mutect2, varscan2
- PCDHA6 | c.146C>A p.A49E | Missense Mutation (SNP) | VAF 314/659 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs781807408, COSV65351636; called by muse, mutect2, varscan2
- PDE4D | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 180/373 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs867397273; called by muse, mutect2, varscan2
- PDE4DIP | c.6884G>A p.S2295N | Missense Mutation (SNP) | VAF 99/419 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV100518844; called by muse, mutect2, varscan2
- PIMREG | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 260/582 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.664); catalogued as rs1272345349; called by muse, mutect2, varscan2
- PKHD1 | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 30/537 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV61896113; called by muse, mutect2
- POLL | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 242/489 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs149081648; called by muse, mutect2, varscan2
- POLN | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 50/521 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs190634789; called by muse, mutect2
- POMT1 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1292313849; called by muse, mutect2, varscan2
- PPP6R1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 24/630 reads (4%) | catalogued as COSV101337005; called by muse, mutect2
- PRDM16 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 38/598 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757773480; called by muse, mutect2
- PRICKLE3 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 346/732 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as rs370668964; called by muse, varscan2
- PRIMPOL | c.183C>T p.D61= | Splice Region (SNP) | VAF 130/293 reads (44%) | catalogued as rs145216655; called by muse, mutect2
- PRRC2A | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 186/559 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs750688400, COSV63224864; called by muse, mutect2, varscan2
- PTPRD | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 177/350 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100643981; called by muse, mutect2, varscan2
- PWP2 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 156/202 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764962504; called by muse, mutect2, varscan2
- RALGDS | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 220/418 reads (53%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.615); catalogued as rs148398301; called by muse, mutect2, varscan2
- RAVER1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 278/550 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs776468563, COSV53349496; called by muse, mutect2, varscan2
- RBM15B | c.1608_1610del p.L537del | In Frame Del (DEL) | VAF 234/505 reads (46%) | catalogued as rs1258957852; called by mutect2, varscan2
- RNF126 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 140/480 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139851549; called by muse, mutect2, varscan2
- RNF165 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 299/619 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV53972037; called by muse, mutect2, varscan2
- RPS6KA1 | c.1324A>G p.M442V | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs772096189; called by muse, mutect2, varscan2
- RXRA | c.331del p.L111Wfs*57 | Frame Shift Del (DEL) | VAF 279/570 reads (49%) | catalogued as COSV62684236; called by mutect2, varscan2
- SALL3 | c.2672C>T p.A891V | Missense Mutation (SNP) | VAF 373/759 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs751561264; called by muse, mutect2, varscan2
- SCARB1 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 69/592 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs780067272; called by muse, mutect2, varscan2
- SDF2L1 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 260/541 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781535370; called by muse, mutect2, varscan2
- SH3PXD2B | c.2048G>T p.G683V | Missense Mutation (SNP) | VAF 26/678 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV100288226; called by muse, mutect2
- SHANK1 | c.6442C>T p.R2148C | Missense Mutation (SNP) | VAF 201/407 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99521318; called by muse, mutect2, varscan2
- SIN3B | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 172/354 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.416); catalogued as COSV56134011; called by muse, varscan2
- SLC12A7 | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 153/310 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs1187222840; called by muse, mutect2, varscan2
- SLC35A4 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 254/522 reads (49%) | catalogued as rs775493102; called by muse, mutect2, varscan2
- SLC37A2 | c.1196del p.G399Afs*24 | Frame Shift Del (DEL) | VAF 170/346 reads (49%) | catalogued as COSV53524083; called by mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 142/478 reads (30%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SLC5A7 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 210/433 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs748755332, COSV50891064; called by muse, mutect2, varscan2
- SMARCE1 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 70/542 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52860799; called by muse, mutect2, varscan2
- SMC1A | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 272/579 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs782636271; called by muse, mutect2, varscan2
- SMO | c.1464G>A p.V488= | Splice Region (SNP) | VAF 134/290 reads (46%) | catalogued as rs1384472073, COSV50838661; called by muse, mutect2, varscan2
- SMPD4 | c.1768C>T p.R590C (on ENST00000409031 / NM_017951.4; = p.R561C on NM_017751.4) | Missense Mutation (SNP) | VAF 132/285 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752750090, COSV100302457; called by muse, mutect2, varscan2
- SOX3 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 331/696 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65168347; called by muse, mutect2, varscan2
- SRPK2 | c.1736C>T p.T579M | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464437240; called by muse, mutect2
- SSX1 | c.425del p.P142Qfs*34 | Frame Shift Del (DEL) | VAF 82/406 reads (20%) | catalogued as rs782023583, COSV100976380; called by mutect2, varscan2
- STK32B | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 250/511 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs553561922, COSV51494342; called by muse, mutect2, varscan2
- SUPT5H | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 261/553 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316671406; called by muse, mutect2, varscan2
- SYNPO | c.2026C>T p.Q676* (on ENST00000394243 / NM_001166208.2; = p.Q432* on NM_007286.6) | Nonsense Mutation (SNP) | VAF 320/715 reads (45%) | catalogued as COSV56938757; called by muse, mutect2, varscan2
- TAS2R31 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 335/645 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1283986544, COSV101114746; called by muse, mutect2, varscan2
- TDRD6 | c.2750del p.N917Ifs*2 | Frame Shift Del (DEL) | VAF 124/267 reads (46%) | catalogued as COSV60174471; called by mutect2, varscan2
- TIMM17B | c.212dup p.L72Pfs*56 | Frame Shift Ins (INS) | VAF 184/428 reads (43%) | catalogued as rs782500597; called by mutect2, varscan2
- TKTL2 | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 191/403 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1427508528; called by muse, mutect2, varscan2
- TMEM178B | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 328/666 reads (49%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.554); catalogued as rs1357734081; called by muse, mutect2, varscan2
- TNRC18 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 60/488 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1218623372; called by muse, mutect2, varscan2
- TNRC6B | c.4006T>C p.S1336P (on ENST00000454349 / NM_001162501.2; = p.S1226P on NM_015088.3) | Missense Mutation (SNP) | VAF 298/594 reads (50%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.524); catalogued as rs1244593172; called by muse, mutect2, varscan2
- TRAM2 | c.1019G>T p.R340M | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs778188890, COSV99480432; called by muse, mutect2
- TRPM5 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 69/560 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs758079989; called by muse, varscan2
- TTLL11 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 177/517 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs1333698139, COSV58645384; called by muse, mutect2, varscan2
- TTN | c.13351G>A p.G4451S (on ENST00000591111; = p.G4405S on NM_003319.4) | Missense Mutation (SNP) | VAF 192/423 reads (45%) | PolyPhen probably damaging (0.962); catalogued as rs727503652; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- UNC79 | c.4595C>T p.P1532L (on ENST00000393151 / NM_001346218.2; = p.P1355L on NM_020818.5) | Missense Mutation (SNP) | VAF 56/599 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.168); catalogued as rs1318086244, COSV56420959; called by muse, mutect2
- USP19 | c.2267C>T p.T756M | Missense Mutation (SNP) | VAF 232/494 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs369169271; called by muse, mutect2, varscan2
- WDR44 | c.417del p.K139Nfs*13 | Frame Shift Del (DEL) | VAF 174/490 reads (36%) | catalogued as COSV54162754; called by mutect2, varscan2
- YY1 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 120/231 reads (52%) | catalogued as COSV51764900; called by muse, mutect2, varscan2
- ZAR1L | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 13/415 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs950022307; called by muse, mutect2
- ZMIZ1 | c.2743A>G p.M915V | Missense Mutation (SNP) | VAF 66/651 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV57890608; called by muse, mutect2
- ZNF512B | c.2192C>T p.T731M | Missense Mutation (SNP) | VAF 209/434 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs754690373; called by muse, mutect2, varscan2
- ZNF512B | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 219/653 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs771449991; called by muse, mutect2, varscan2
- ZNF668 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 393/836 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759082830, COSV100336741; called by muse, mutect2, varscan2
- ZNF678 | c.1563del p.K521Nfs*30 | Frame Shift Del (DEL) | VAF 69/229 reads (30%) | catalogued as rs763710563; called by mutect2, varscan2
- ZNF83 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 224/440 reads (51%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as rs762225164, COSV99991334; called by muse, mutect2, varscan2
- ZNF835 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 333/684 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1267768322; called by muse, mutect2, varscan2
- ZP2 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761335280; called by muse, mutect2
- ZSWIM8 | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 215/618 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV101290061; called by muse, mutect2, varscan2
- AAAS | c.270del p.F90Lfs*4 | Frame Shift Del (DEL) | VAF 166/340 reads (49%) | called by mutect2, varscan2
- AC244197.3 | c.957G>T p.L319F | Missense Mutation (SNP) | VAF 233/455 reads (51%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ADGRA1 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 314/658 reads (48%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ADGRE1 | c.2539C>T p.L847F | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRL1 | c.2273del p.G758Afs*4 (on ENST00000340736 / NM_001008701.3; = p.G753Afs*4 on NM_014921.5) | Frame Shift Del (DEL) | VAF 68/614 reads (11%) | called by mutect2, varscan2
- AIFM2 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 167/370 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- AKAP9 | c.11271A>C p.E3757D (on ENST00000359028; = p.E3733D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/583 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANPEP | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 264/536 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ARFGAP3 | c.669dup p.G224Rfs*20 | Frame Shift Ins (INS) | VAF 56/152 reads (37%) | called by mutect2, varscan2
- ARHGAP25 | c.1225C>T p.P409S (on ENST00000409202 / NM_001007231.3; = p.P401S on NM_014882.3) | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- ARHGAP29 | c.2364del p.K788Nfs*7 | Frame Shift Del (DEL) | VAF 124/270 reads (46%) | called by mutect2, varscan2
- ARID1B | c.3023A>G p.E1008G | Missense Mutation (SNP) | VAF 159/357 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ARID3A | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 97/312 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID3A | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 17/522 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.028); called by muse, mutect2
- ARIH1 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 256/538 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, varscan2
- ARL13B | c.838dup p.M280Nfs*6 (on ENST00000394222 / NM_001174150.2; = p.M173Nfs*6 on NM_144996.4) | Frame Shift Ins (INS) | VAF 108/270 reads (40%) | called by mutect2, varscan2
- ARX | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 382/782 reads (49%) | SIFT tolerated, low confidence (0.61); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ATXN7L1 | c.641A>T p.N214I | Missense Mutation (SNP) | VAF 145/414 reads (35%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATXN7L3 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 274/603 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- BACH2 | c.819dup p.Q274Afs*3 | Frame Shift Ins (INS) | VAF 243/534 reads (46%) | called by mutect2, varscan2
- BCL11B | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 62/594 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- BRD3 | c.1509_1514del p.D503_K504del | In Frame Del (DEL) | VAF 212/465 reads (46%) | called by mutect2, varscan2
- BRINP1 | c.117T>G p.D39E | Missense Mutation (SNP) | VAF 197/455 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- BRWD3 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 114/281 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C5orf38 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 222/508 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.917); called by muse, varscan2
- CACNA1E | c.2600T>G p.L867R | Missense Mutation (SNP) | VAF 28/806 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2
- CACNG8 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 357/735 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CCDC148 | c.1260del p.K420Nfs*15 | Frame Shift Del (DEL) | VAF 97/234 reads (41%) | called by mutect2, varscan2
- CD2AP | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 112/258 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH22 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 296/578 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CDK11B | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 74/358 reads (21%) | called by muse, varscan2
- CDK5RAP2 | c.1688T>C p.I563T | Missense Mutation (SNP) | VAF 162/443 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CHRD | c.767T>A p.V256E | Missense Mutation (SNP) | VAF 287/629 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHTF18 | c.2179dup p.Q727Pfs*59 | Frame Shift Ins (INS) | VAF 118/305 reads (39%) | called by mutect2, varscan2
- CLIC3 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 286/609 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CNIH4 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 206/423 reads (49%) | SIFT tolerated (0.79); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- COBLL1 | c.846dup p.Q283Sfs*4 (on ENST00000392717; = p.Q245Sfs*4 on NM_014900.5) | Frame Shift Ins (INS) | VAF 20/188 reads (11%) | called by mutect2, varscan2
- CREB1 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 161/367 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CTAGE9 | c.908del p.N303Mfs*5 | Frame Shift Del (DEL) | VAF 64/522 reads (12%) | called by mutect2, varscan2
- CTC1 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 244/546 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP21A2 | c.793del p.V265Wfs*26 | Frame Shift Del (DEL) | VAF 108/850 reads (13%) | called by mutect2, varscan2
- DENND4C | c.5749G>A p.D1917N (on ENST00000434457 / NM_001330640.2; = p.D1868N on NM_017925.7) | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLAT | c.1355T>C p.V452A | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- DPPA2 | c.35A>T p.N12I | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- DYNC1H1 | c.6352C>T p.R2118* | Nonsense Mutation (SNP) | VAF 194/409 reads (47%) | called by muse, mutect2, varscan2
- E2F1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 229/697 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ELF3 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 26/471 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2
- EP400 | c.8047C>A p.L2683M | Missense Mutation (SNP) | VAF 31/565 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM13B | c.2346del p.F782Lfs*18 | Frame Shift Del (DEL) | VAF 150/278 reads (54%) | called by mutect2, varscan2
- FAM199X | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 49/794 reads (6%) | called by muse, mutect2
- FBXL6 | c.99G>T p.R33S | Missense Mutation (SNP) | VAF 208/605 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FKBP4 | c.401T>C p.L134S | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FN1 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 179/439 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRE | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 275/556 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GAGE12H | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 149/1462 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, varscan2
- GDPD2 | c.588dup p.G197Wfs*53 | Frame Shift Ins (INS) | VAF 165/468 reads (35%) | called by mutect2, varscan2
- GHDC | c.1580G>T p.R527M | Missense Mutation (SNP) | VAF 92/474 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- GNGT2 | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 193/406 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- GNS | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 331/682 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 50/904 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- GPC6 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 224/433 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GPR26 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 190/364 reads (52%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HERC2 | c.12998T>C p.M4333T | Missense Mutation (SNP) | VAF 209/428 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- HNRNPUL2 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 228/490 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- HSD3B7 | c.543dup p.L182Afs*16 | Frame Shift Ins (INS) | VAF 164/403 reads (41%) | called by mutect2, varscan2
- ICE1 | c.978del p.F326Lfs*82 | Frame Shift Del (DEL) | VAF 156/389 reads (40%) | called by mutect2, varscan2
- IRF6 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 216/485 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITPRIPL2 | c.1041G>T p.W347C | Missense Mutation (SNP) | VAF 37/580 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- KIAA0319L | c.1224del p.I409Lfs*43 | Frame Shift Del (DEL) | VAF 149/287 reads (52%) | called by mutect2, varscan2
- KLRC3 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 129/309 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- KMT2A | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 189/440 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT5 | c.1403C>G p.A468G | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- LAMA2 | c.2662A>G p.I888V | Missense Mutation (SNP) | VAF 173/420 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- LETM1 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRCH2 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 287/804 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- LRIG3 | c.1827del p.M610Wfs*25 | Frame Shift Del (DEL) | VAF 170/354 reads (48%) | called by mutect2, varscan2
- LRRC4B | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 354/698 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LRRD1 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 158/406 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- MAP3K15 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MCM9 | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 38/405 reads (9%) | called by muse, mutect2
- ME2 | c.1436T>C p.I479T | Missense Mutation (SNP) | VAF 27/326 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.435); called by muse, mutect2
- MEST | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 243/500 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MINDY3 | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MIS18BP1 | c.1764del p.E589Nfs*9 | Frame Shift Del (DEL) | VAF 32/122 reads (26%) | called by mutect2, varscan2
- MRPL4 | c.640del p.D214Tfs*8 | Frame Shift Del (DEL) | VAF 146/356 reads (41%) | called by mutect2, varscan2
- MRTFB | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 169/372 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MTRF1 | c.415del p.S139Afs*2 | Frame Shift Del (DEL) | VAF 63/194 reads (32%) | called by mutect2, varscan2
- MYO15A | c.8474T>G p.L2825R | Missense Mutation (SNP) | VAF 49/345 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- N4BP2 | c.3623C>G p.A1208G | Missense Mutation (SNP) | VAF 146/415 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NAPG | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 136/314 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEFM | c.2162del p.K721Rfs*18 | Frame Shift Del (DEL) | VAF 196/432 reads (45%) | called by mutect2, varscan2
- NFATC2 | c.2654del p.K885Rfs*8 | Frame Shift Del (DEL) | VAF 231/474 reads (49%) | called by mutect2, varscan2
- NPC1L1 | c.3575C>A p.A1192D | Missense Mutation (SNP) | VAF 189/389 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NPEPL1 | c.1211G>T p.C404F | Missense Mutation (SNP) | VAF 259/577 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- NRXN2 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 53/500 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, varscan2
- NYAP2 | c.945del p.K316Rfs*57 | Frame Shift Del (DEL) | VAF 210/454 reads (46%) | called by mutect2, varscan2
- OBSCN | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 70/612 reads (11%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODF4 | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 157/503 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- OR4C13 | c.881del p.N294Mfs*24 | Frame Shift Del (DEL) | VAF 68/234 reads (29%) | called by mutect2, varscan2
- OR4D11 | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 206/400 reads (52%) | called by muse, mutect2, varscan2
- PARD3B | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- PAWR | c.908T>A p.L303H | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PAX3 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- PCDHGA2 | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PERCC1 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 208/428 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, varscan2
- PHYHIP | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 186/635 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PIGN | c.620dup p.H209Tfs*24 | Frame Shift Ins (INS) | VAF 66/155 reads (43%) | called by mutect2, varscan2
- PIWIL3 | c.2464A>G p.I822V | Missense Mutation (SNP) | VAF 20/586 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2
- PLA2R1 | c.3823G>A p.A1275T | Missense Mutation (SNP) | VAF 128/301 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLEC | c.5071C>T p.Q1691* (on ENST00000322810 / NM_201380.4; = p.Q1581* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 80/760 reads (11%) | called by muse, varscan2
- PLEKHH2 | c.3518G>A p.G1173D | Missense Mutation (SNP) | VAF 55/403 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLXNB2 | c.2438G>C p.G813A | Missense Mutation (SNP) | VAF 214/459 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- POLQ | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR2E | c.194A>C p.N65T | Missense Mutation (SNP) | VAF 277/548 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRKDC | c.6479A>T p.Y2160F | Missense Mutation (SNP) | VAF 156/325 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRSS53 | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 99/731 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PSMB8 | c.414C>G p.Y138* (on ENST00000374882 / NM_148919.4; = p.Y134* on NM_004159.5) | Nonsense Mutation (SNP) | VAF 202/424 reads (48%) | called by muse, mutect2, varscan2
- QSOX1 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 265/579 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF19A | c.187del p.R63Efs*5 | Frame Shift Del (DEL) | VAF 154/314 reads (49%) | called by mutect2, varscan2
- SASS6 | c.1967del p.N656Tfs*15 | Frame Shift Del (DEL) | VAF 60/296 reads (20%) | called by mutect2, varscan2
- SCARF2 | c.1328T>C p.V443A | Missense Mutation (SNP) | VAF 56/643 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.557); called by muse, mutect2
- SEMA3F | c.863A>G p.Q288R | Missense Mutation (SNP) | VAF 133/387 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SENP3 | c.568del p.R190Gfs*11 | Frame Shift Del (DEL) | VAF 309/712 reads (43%) | called by mutect2, varscan2
- SHC3 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 289/587 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SLC12A7 | c.2153T>C p.L718P | Missense Mutation (SNP) | VAF 388/872 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SLC25A17 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 11/249 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- SLC29A3 | c.665C>G p.A222G | Missense Mutation (SNP) | VAF 217/503 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLC52A1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 219/436 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMIM10L2A | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 298/652 reads (46%) | SIFT tolerated (0.4); called by muse, mutect2, varscan2
- SNPH | c.947C>T p.T316I | Missense Mutation (SNP) | VAF 317/613 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SON | c.3447G>C p.L1149F | Missense Mutation (SNP) | VAF 244/492 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SORCS3 | c.109T>C p.W37R | Missense Mutation (SNP) | VAF 256/695 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- SOX3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); called by muse, mutect2
- SPAG1 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 165/394 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK25 | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 46/490 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STK3 | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 179/427 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- SYNE1 | c.24108G>T p.K8036N (on ENST00000367255 / NM_182961.4; = p.K7965N on NM_033071.3) | Missense Mutation (SNP) | VAF 29/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNE2 | c.8520del p.F2840Lfs*3 | Frame Shift Del (DEL) | VAF 40/290 reads (14%) | called by mutect2, varscan2
- TAF4B | c.1799del p.N600Ifs*3 | Frame Shift Del (DEL) | VAF 120/258 reads (47%) | called by mutect2, varscan2
- TGM6 | c.1078del p.Q360Rfs*99 | Frame Shift Del (DEL) | VAF 200/417 reads (48%) | called by mutect2, varscan2
- TMDD1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 225/484 reads (46%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TMEM129 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 289/552 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM38B | c.286del p.C96Afs*5 | Frame Shift Del (DEL) | VAF 108/222 reads (49%) | called by mutect2, varscan2
- TRAPPC3 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2
- TRAT1 | c.50T>G p.L17W | Missense Mutation (SNP) | VAF 213/401 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- TTN | c.47063del p.K15688Rfs*20 (on ENST00000591111; = p.K8264Rfs*20 on NM_003319.4) | Frame Shift Del (DEL) | VAF 156/322 reads (48%) | called by mutect2, varscan2
- UGT2B28 | c.1373A>G p.H458R | Missense Mutation (SNP) | VAF 199/414 reads (48%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- UPK3B | c.854G>A p.G285D (on ENST00000257632; = p.A257T on NM_001347684.2) | Missense Mutation (SNP) | VAF 74/1065 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- USP53 | c.2959C>T p.Q987* | Nonsense Mutation (SNP) | VAF 212/428 reads (50%) | called by muse, varscan2
- UTF1 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 184/526 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- VCAN | c.3082G>A p.E1028K | Missense Mutation (SNP) | VAF 23/470 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- VIRMA | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- VPS13B | c.8222T>C p.I2741T | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VWDE | c.1430G>A p.C477Y | Missense Mutation (SNP) | VAF 200/406 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASL | c.233del p.L78* | Frame Shift Del (DEL) | VAF 84/259 reads (32%) | called by mutect2, varscan2
- XIRP2 | c.1877T>A p.V626D (on ENST00000628543; = p.V801D on NM_152381.6) | Missense Mutation (SNP) | VAF 51/432 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- YTHDC2 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 117/241 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB34 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 240/484 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB7C | c.960del p.P321Lfs*18 | Frame Shift Del (DEL) | VAF 185/455 reads (41%) | called by mutect2, varscan2
- ZKSCAN8 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 16/544 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.172); called by muse, mutect2
- ZNF292 | c.4640T>C p.L1547P | Missense Mutation (SNP) | VAF 94/447 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF337 | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 218/460 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, varscan2
- ZNF519 | c.726del p.K242Nfs*3 | Frame Shift Del (DEL) | VAF 38/292 reads (13%) | called by mutect2, varscan2
- ZNF852 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 162/340 reads (48%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- A3GALT2 | c.576G>A p.A192= | Silent (SNP) | VAF 255/516 reads (49%) | called by muse, mutect2, varscan2
- ABCA2 | c.3066C>T p.C1022= (on ENST00000614293; = p.C992= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 269/541 reads (50%) | catalogued as rs768859234; called by muse, mutect2, varscan2
- ABCA6 | c.1110A>G p.G370= | Silent (SNP) | VAF 106/234 reads (45%) | called by muse, mutect2, varscan2
- ADGRA1 | c.477A>G p.L159= | Silent (SNP) | VAF 111/240 reads (46%) | called by muse, mutect2, varscan2
- ADIPOR2 | c.147T>G p.S49= | Silent (SNP) | VAF 137/286 reads (48%) | called by muse, mutect2, varscan2
- AGTRAP | c.252G>A p.T84= | Silent (SNP) | VAF 183/552 reads (33%) | catalogued as rs1375489379; called by muse, varscan2
- ANGPTL2 | c.453C>T p.N151= | Silent (SNP) | VAF 58/644 reads (9%) | catalogued as rs377308519, COSV99401386; called by muse, mutect2
- APLNR | c.186C>A p.R62= | Silent (SNP) | VAF 245/508 reads (48%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.1371G>A p.R457= | Silent (SNP) | VAF 138/172 reads (80%) | catalogued as rs1423578342; called by muse, mutect2, varscan2
- ASPM | c.8949T>C p.I2983= | Silent (SNP) | VAF 143/284 reads (50%) | called by muse, mutect2, varscan2
- BEND3 | c.726G>A p.P242= | Silent (SNP) | VAF 245/516 reads (47%) | catalogued as rs782812529; called by muse, mutect2, varscan2
- BST1 | c.882A>G p.P294= | Silent (SNP) | VAF 42/366 reads (11%) | catalogued as rs774618205; called by muse, mutect2, varscan2
- C11orf95 | c.975C>A p.A325= | Silent (SNP) | VAF 22/816 reads (3%) | called by muse, mutect2
- C16orf46 | c.642G>C p.L214= | Silent (SNP) | VAF 284/599 reads (47%) | catalogued as COSV55150130; called by muse, mutect2, varscan2
- C2CD4D | c.195C>T p.P65= | Silent (SNP) | VAF 100/578 reads (17%) | called by muse, mutect2, varscan2
- CCDC178 | c.2235C>T p.T745= (on ENST00000383096 / NM_001105528.3; = p.T707= on NM_198995.3) | Silent (SNP) | VAF 78/170 reads (46%) | called by muse, mutect2, varscan2
- CDK5RAP1 | c.732C>T p.S244= | Silent (SNP) | VAF 148/335 reads (44%) | catalogued as rs1169087332; called by muse, mutect2, varscan2
- CDON | c.3489C>T p.S1163= | Silent (SNP) | VAF 19/543 reads (3%) | catalogued as rs1193053529, COSV99701804; called by muse, mutect2
- CECR2 | c.783C>T p.R261= (on ENST00000342247 / NM_001290047.2; = p.R98= on NM_001290046.1) | Silent (SNP) | VAF 226/449 reads (50%) | catalogued as rs766186451, COSV52848326; called by muse, mutect2, varscan2
- CEP85 | c.1908A>G p.S636= | Silent (SNP) | VAF 131/263 reads (50%) | catalogued as rs1300824821; called by muse, mutect2, varscan2
- CNDP2 | c.936G>A p.P312= | Silent (SNP) | VAF 232/454 reads (51%) | catalogued as rs781276053; called by muse, mutect2, varscan2
- CNNM1 | c.2538C>T p.D846= | Silent (SNP) | VAF 171/344 reads (50%) | catalogued as rs116405851; called by muse, mutect2, varscan2
- COL18A1 | c.3351C>T p.L1117= (on ENST00000359759 / NM_130444.3; = p.L882= on NM_030582.4) | Silent (SNP) | VAF 245/524 reads (47%) | called by muse, mutect2, varscan2
- CSN2 | c.465G>A p.Q155= | Silent (SNP) | VAF 253/525 reads (48%) | catalogued as rs1327190827; called by muse, varscan2
- DAP | c.201C>T p.D67= | Silent (SNP) | VAF 125/290 reads (43%) | called by muse, mutect2, varscan2
- DCHS2 | c.237G>A p.P79= | Silent (SNP) | VAF 292/669 reads (44%) | catalogued as rs753869173; called by muse, mutect2, varscan2
- DLEC1 | c.4275C>T p.Y1425= | Silent (SNP) | VAF 122/331 reads (37%) | catalogued as rs368123121; called by muse, mutect2, varscan2
- DSCAM | c.4759C>T p.L1587= | Silent (SNP) | VAF 55/459 reads (12%) | catalogued as COSV68020261, COSV68028306; called by muse, mutect2, varscan2
- DYTN | c.1119A>G p.Q373= | Silent (SNP) | VAF 142/385 reads (37%) | called by muse, mutect2, varscan2
- EFCAB6 | c.4320G>A p.R1440= | Silent (SNP) | VAF 44/556 reads (8%) | called by muse, mutect2
- ELFN1 | c.1813C>T p.L605= | Silent (SNP) | VAF 211/720 reads (29%) | called by muse, mutect2, varscan2
- EXT1 | c.1179C>T p.I393= | Silent (SNP) | VAF 119/251 reads (47%) | catalogued as COSV100984117; called by muse, mutect2, varscan2
- FAM155B | c.36C>T p.D12= | Silent (SNP) | VAF 255/514 reads (50%) | catalogued as COSV52936437; called by muse, varscan2
- FBXW4 | c.1326C>T p.G442= | Silent (SNP) | VAF 18/465 reads (4%) | called by muse, mutect2
- FXYD6 | c.204G>A p.K68= | Silent (SNP) | VAF 170/366 reads (46%) | called by muse, mutect2, varscan2
- GATA4 | c.177G>A p.A59= | Silent (SNP) | VAF 331/735 reads (45%) | catalogued as rs1248717520; called by muse, mutect2, varscan2
- GPR101 | c.1245C>T p.Y415= | Silent (SNP) | VAF 336/683 reads (49%) | called by muse, mutect2, varscan2
- GPR158 | c.300C>A p.S100= | Silent (SNP) | VAF 66/582 reads (11%) | catalogued as COSV100892954; called by mutect2, varscan2
- GSE1 | c.2046C>A p.T682= | Silent (SNP) | VAF 338/724 reads (47%) | called by muse, mutect2, varscan2
- GSX1 | c.759A>G p.S253= | Silent (SNP) | VAF 197/426 reads (46%) | catalogued as rs138515715; called by muse, varscan2
- GUCA1B | c.102C>T p.S34= | Silent (SNP) | VAF 141/453 reads (31%) | catalogued as rs151297895; called by muse, mutect2, varscan2
- HMGXB4 | c.1752A>G p.K584= | Silent (SNP) | VAF 22/374 reads (6%) | called by muse, mutect2
- HRH3 | c.591C>T p.Y197= | Silent (SNP) | VAF 251/543 reads (46%) | catalogued as rs201285011, COSV58050304; called by muse, mutect2, varscan2
- IGDCC4 | c.3744C>A p.S1248= | Silent (SNP) | VAF 159/399 reads (40%) | called by muse, mutect2, varscan2
- IGHG1 | c.657C>A p.I219= | Silent (SNP) | VAF 308/655 reads (47%) | called by muse, mutect2, varscan2
- IRX2 | c.993G>A p.S331= | Silent (SNP) | VAF 282/570 reads (49%) | catalogued as COSV57412226; called by muse, mutect2, varscan2
- KBTBD13 | c.756G>A p.A252= | Silent (SNP) | VAF 310/626 reads (50%) | catalogued as rs1431328866; called by muse, mutect2, varscan2
- KIAA1109 | c.13182C>T p.S4394= | Silent (SNP) | VAF 198/403 reads (49%) | called by muse, mutect2, varscan2
- KIAA2026 | c.3447A>G p.L1149= | Silent (SNP) | VAF 197/405 reads (49%) | catalogued as rs766216619; called by muse, mutect2, varscan2
- KIF13B | c.1422G>T p.G474= | Silent (SNP) | VAF 107/210 reads (51%) | called by muse, mutect2, varscan2
- KLHL34 | c.240G>A p.L80= | Silent (SNP) | VAF 152/620 reads (25%) | called by muse, mutect2, varscan2
- LIX1 | c.96A>G p.S32= | Silent (SNP) | VAF 23/281 reads (8%) | called by muse, mutect2
- LMNTD2 | c.24C>A p.G8= | Silent (SNP) | VAF 277/583 reads (48%) | called by muse, mutect2, varscan2
- LNX2 | c.1809A>G p.L603= | Silent (SNP) | VAF 51/335 reads (15%) | called by muse, mutect2, varscan2
- MAN2A1 | c.603A>G p.L201= | Silent (SNP) | VAF 161/313 reads (51%) | called by muse, mutect2, varscan2
- MAP3K19 | c.2031T>C p.T677= | Silent (SNP) | VAF 187/363 reads (52%) | called by muse, mutect2, varscan2
- MICAL3 | c.1131C>G p.S377= | Silent (SNP) | VAF 293/534 reads (55%) | called by muse, mutect2, varscan2
- MMAB | c.150G>A p.S50= | Silent (SNP) | VAF 41/453 reads (9%) | catalogued as rs754357121, COSV57169393; called by muse, mutect2
- MSANTD2 | c.1083C>T p.T361= (on ENST00000374979 / NM_001308027.2; = p.T309= on NM_024631.4) | Silent (SNP) | VAF 243/470 reads (52%) | catalogued as rs753485901; called by muse, mutect2, varscan2
- MTMR4 | c.774C>A p.A258= | Silent (SNP) | VAF 225/498 reads (45%) | called by muse, mutect2, varscan2
- NEK2 | c.1335C>T p.R445= | Silent (SNP) | VAF 185/378 reads (49%) | catalogued as COSV65356407; called by muse, mutect2
- NKAPL | c.306A>G p.A102= | Silent (SNP) | VAF 71/490 reads (14%) | catalogued as rs1250080995; called by muse, mutect2, varscan2
- OBSCN | c.5247G>T p.T1749= | Silent (SNP) | VAF 335/687 reads (49%) | catalogued as COSV52806743; called by muse, mutect2, varscan2
- OR2I1P | c.72G>T p.P24= | Silent (SNP) | VAF 192/418 reads (46%) | catalogued as rs534371251; called by muse, mutect2, varscan2
- PCDHGA5 | c.2154C>T p.R718= | Silent (SNP) | VAF 278/589 reads (47%) | called by muse, varscan2
- PCNT | c.900G>A p.Q300= | Silent (SNP) | VAF 218/628 reads (35%) | called by muse, mutect2, varscan2
- PLCH2 | c.3051G>A p.P1017= | Silent (SNP) | VAF 77/694 reads (11%) | called by muse, mutect2, varscan2
- PLSCR2 | c.141T>C p.H47= | Silent (SNP) | VAF 195/427 reads (46%) | called by muse, mutect2, varscan2
- PPFIA3 | c.222C>T p.L74= | Silent (SNP) | VAF 123/268 reads (46%) | called by muse, mutect2, varscan2
- PPFIA3 | c.477C>T p.L159= | Silent (SNP) | VAF 160/314 reads (51%) | catalogued as COSV100495112; called by muse, varscan2
- PPP1R1A | c.379C>T p.L127= | Silent (SNP) | VAF 49/529 reads (9%) | called by muse, mutect2
- PRKAG3 | c.1302C>T p.C434= | Silent (SNP) | VAF 245/526 reads (47%) | catalogued as rs868202669; called by muse, mutect2, varscan2
- PTEN | c.381A>T p.G127= | Silent (SNP) | VAF 206/408 reads (50%) | called by muse, mutect2, varscan2
- RGS14 | c.825A>G p.L275= | Silent (SNP) | VAF 15/456 reads (3%) | called by muse, mutect2
- RNF128 | c.369C>T p.G123= | Silent (SNP) | VAF 149/459 reads (32%) | catalogued as rs764419162; called by muse, mutect2, varscan2
- SCAF1 | c.1140G>A p.P380= | Silent (SNP) | VAF 69/565 reads (12%) | catalogued as rs1391798338; called by muse, mutect2, varscan2
- SCAP | c.3823C>T p.L1275= | Silent (SNP) | VAF 120/331 reads (36%) | catalogued as rs993413484; called by muse, mutect2, varscan2
- SEMA5A | c.2241A>G p.R747= | Silent (SNP) | VAF 139/388 reads (36%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.1506C>T p.R502= | Silent (SNP) | VAF 26/486 reads (5%) | called by muse, mutect2
- SLC19A1 | c.763C>T p.L255= | Silent (SNP) | VAF 303/650 reads (47%) | called by muse, mutect2, varscan2
- SLC26A8 | c.2328C>T p.D776= | Silent (SNP) | VAF 184/395 reads (47%) | catalogued as rs116555814; called by muse, mutect2, varscan2
- SLC6A17 | c.432C>T p.F144= | Silent (SNP) | VAF 160/332 reads (48%) | catalogued as rs1334090420; called by muse, mutect2, varscan2
- SNPH | c.1332C>T p.C444= | Silent (SNP) | VAF 26/733 reads (4%) | called by muse, mutect2
- SOBP | c.2553C>T p.S851= | Silent (SNP) | VAF 240/461 reads (52%) | called by muse, mutect2, varscan2
- SOX11 | c.831C>A p.A277= | Silent (SNP) | VAF 267/527 reads (51%) | catalogued as COSV58983858; called by muse, mutect2, varscan2
- STARD8 | c.942C>T p.H314= | Silent (SNP) | VAF 346/639 reads (54%) | catalogued as rs143103482; called by muse, mutect2, varscan2
- SUN1 | c.1059G>A p.S353= (on ENST00000405266 / NM_001367651.1; = p.S233= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 85/378 reads (22%) | catalogued as rs776253918; called by muse, mutect2, varscan2
- SYNGAP1 | c.549T>C p.H183= | Silent (SNP) | VAF 98/470 reads (21%) | catalogued as rs1244176054, COSV53386407; called by muse, mutect2, varscan2
- TGFB3 | c.483T>C p.S161= | Silent (SNP) | VAF 36/428 reads (8%) | called by muse, mutect2
- TLNRD1 | c.1062G>A p.P354= | Silent (SNP) | VAF 175/345 reads (51%) | catalogued as rs370704886; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4740G>A p.K1580= | Silent (SNP) | VAF 237/677 reads (35%) | catalogued as rs1377457543; called by muse, mutect2, varscan2
- TPP2 | c.747C>T p.Y249= | Silent (SNP) | VAF 185/363 reads (51%) | catalogued as rs945024942, COSV65753922; called by muse, mutect2, varscan2
- TRIOBP | c.5367C>T p.D1789= (on ENST00000644935 / NM_001039141.3; = p.D76= on NM_007032.5) | Silent (SNP) | VAF 178/395 reads (45%) | catalogued as rs778567541; called by muse, varscan2
- TTN | c.50142T>C p.A16714= (on ENST00000591111; = p.A9290= on NM_003319.4) | Silent (SNP) | VAF 24/469 reads (5%) | called by muse, mutect2
- UBE2S | c.306C>T p.D102= | Silent (SNP) | VAF 165/370 reads (45%) | called by muse, mutect2, varscan2
- UIMC1 | c.978T>C p.P326= | Silent (SNP) | VAF 149/477 reads (31%) | called by muse, mutect2, varscan2
- VSTM5 | c.156G>A p.L52= | Silent (SNP) | VAF 219/455 reads (48%) | called by muse, mutect2, varscan2
- WDR6 | c.2409G>A p.V803= | Silent (SNP) | VAF 81/617 reads (13%) | catalogued as rs753765626; called by muse, mutect2, varscan2
- WRAP53 | c.867C>T p.G289= | Silent (SNP) | VAF 224/472 reads (47%) | called by muse, mutect2, varscan2
- XYLT2 | c.423C>T p.H141= | Silent (SNP) | VAF 307/681 reads (45%) | catalogued as rs777978882; called by muse, mutect2, varscan2
- YBX3 | c.603C>T p.S201= | Silent (SNP) | VAF 174/358 reads (49%) | catalogued as rs750604266, COSV54384800; called by muse, varscan2
- ZBTB40 | c.3696G>A p.T1232= | Silent (SNP) | VAF 110/325 reads (34%) | catalogued as rs762594669, COSV65146502; called by muse, mutect2, varscan2
- ZNF407 | c.240G>A p.E80= | Silent (SNP) | VAF 20/414 reads (5%) | catalogued as COSV55276417; called by muse, mutect2
- ZNF516 | c.1431G>A p.P477= | Silent (SNP) | VAF 286/501 reads (57%) | catalogued as rs1291253221, COSV101487323; called by muse, mutect2, varscan2
- ZNF638 | c.3465A>G p.T1155= | Silent (SNP) | VAF 246/460 reads (53%) | catalogued as rs370612354; called by muse, mutect2, varscan2
- ZSCAN16 | c.105C>T p.H35= | Silent (SNP) | VAF 234/491 reads (48%) | catalogued as rs1375538863; called by muse, mutect2, varscan2
- ADAM20 | c.-55T>G | 5'UTR (SNP) | VAF 198/434 reads (46%) | called by muse, mutect2, varscan2
- FGFR3 | c.*180G>A | 3'UTR (SNP) | VAF 233/513 reads (45%) | called by muse, mutect2, varscan2
- FHL1 | c.*64dup | 3'UTR (INS) | VAF 160/342 reads (47%) | called by mutect2, varscan2
- GRK4 | c.52+1246C>T | Intron (SNP) | VAF 184/348 reads (53%) | catalogued as rs1413682604; called by muse, varscan2
- KCNQ1 | c.1733-190G>A | Intron (SNP) | VAF 126/501 reads (25%) | called by muse, mutect2, varscan2
- LARS2 | c.*1013C>T | 3'UTR (SNP) | VAF 56/634 reads (9%) | called by muse, mutect2
- LGI4 | c.794-33G>C | Intron (SNP) | VAF 411/821 reads (50%) | called by muse, mutect2, varscan2
- LSP1 | c.53+13392del | Intron (DEL) | VAF 216/560 reads (39%) | called by mutect2, varscan2
- NGLY1 | c.1004-191del | Intron (DEL) | VAF 76/222 reads (34%) | called by mutect2, varscan2
- ODAPH | c.*38dup | 3'UTR (INS) | VAF 50/362 reads (14%) | catalogued as rs763292297; called by mutect2, varscan2
- OR2V1 | chr5:181130173 C>A | 5'Flank (SNP) | VAF 80/492 reads (16%) | called by muse, mutect2
- OTULINL | c.*4425C>T | 3'UTR (SNP) | VAF 43/335 reads (13%) | catalogued as rs1034650529; called by muse, mutect2, varscan2
- PPM1A | c.952+11dup | Intron (INS) | VAF 126/256 reads (49%) | called by mutect2, varscan2
- SEPTIN6 | chrX:119616734 ins A | 3'Flank (INS) | VAF 37/307 reads (12%) | catalogued as rs1405726294; called by mutect2, varscan2
- SPOCD1 | c.1869-116C>A | Intron (SNP) | VAF 271/520 reads (52%) | called by muse, mutect2, varscan2
- TRIM41 | c.-582del | 5'UTR (DEL) | VAF 56/481 reads (12%) | called by mutect2, varscan2
- YIF1A | c.735+21del | Intron (DEL) | VAF 301/614 reads (49%) | catalogued as rs750015700; called by mutect2, varscan2
